Somatic mutation profile of tumor specimen MP2PRT-PAUKLW-TMP1-A (aliquot MP2PRT-PAUKLW-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUKLW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.7 years (3,166 days).
Specimen MP2PRT-PAUKLW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad8aecad-f6e9-4925-8089-83125d56cfe9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKLW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKLW-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51ff648c-6687-4e87-8548-6c9b698474f1

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 3'Flank 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTHFR | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 80/371 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs757784497; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPE65 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as COSV52016314; called by muse, mutect2, varscan2
- ANKS3 | c.1340_1341insAGTGGAGTAAAGA p.E448Vfs*3 | Nonsense Mutation (INS) | VAF 42/277 reads (15%) | called by mutect2, pindel, varscan2
- CATSPER2 | c.1012G>T p.A338S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- MCCC1 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 17/543 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- TRIM41 | c.137A>G p.Q46R | Missense Mutation (SNP) | VAF 96/448 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.072); called by muse, varscan2
- FSIP2 | c.5505G>A p.S1835= | Silent (SNP) | VAF 34/163 reads (21%) | catalogued as rs752098283; called by muse, mutect2, varscan2
- IGKV1D-16 | chr2:90100738 ins CTTCC | 3'Flank (INS) | VAF 27/198 reads (14%) | called by mutect2, pindel
